Gene-level copy-number profile of tumor specimen C3N-01417-04 from CPTAC case C3N-01417, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 64.2 years (23,444 days).
Specimen C3N-01417-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c8fff4ef-972a-4df1-aed7-f6244276dacb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01417-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/5e959229-8257-4306-8f0d-be5290b339cd

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 514; copy number 1: 306; copy number 2: 1,799; copy number 3: 13,606; copy number 4: 8,961; copy number 5: 8,031; copy number 6: 8,596; copy number 7: 7,649; copy number 8: 2,960; copy number 9: 4,616; copy number 10: 318; copy number 11: 858; copy number 12: 52; copy number 13: 274; copy number 14: 216; copy number 15: 8; copy number 17: 98; copy number 18: 4; copy number 19: 39.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,128,107–12,139,077, 3 genes (within-gene range 0–2): AC130366.1, USP17L7, USP17L2.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 17,092 genes in 54 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:93,921,268–94,963,616, 26 genes, copy number 10: CHCHD2P5, MTND4P11, MTND3P21, MTCO3P21, MTATP6P13, AL117351.2, MTCO2P21, MTCO1P21, AL117351.1, ABCA4, AC093579.1, ARHGAP29, RN7SL440P, ARHGAP29-AS1, GAPDHP29, AC097059.1, AC118469.1, ABCD3, F3, AC093117.1, SLC44A3-AS1, KATNBL1P2, MIR378G, SLC44A3, CNN3, AC105942.1.
- chr1:143,419,625–162,599,842, 848 genes, copy number 9–19 (broad region; genes not listed).
- chr1:162,979,551–163,923,873, 13 genes, copy number 15–19: AL392003.1, RGS4, RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1, U3.
- chr1:214,348,700–221,742,089, 88 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr2:102,736,905–107,748,270, 77 genes, copy number 7 (broad region; genes not listed).
- chr4:51,843,000–62,078,335, 144 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 9 (broad region; genes not listed).
- chr5:107,859,035–109,885,423, 24 genes, copy number 9: FBXL17, AC133134.1, LINC01023, FER, AC034207.1, AC008871.1, Y_RNA, AC109481.1, RNU6-47P, GJA1P1, AC116428.1, AC008467.1, PJA2, AC010625.1, AC091917.3, AC091917.2, AC091917.1, KRT18P42, MAN2A1-DT, MAN2A1, RN7SKP230, AC008417.1, LINC01848, PGAM5P1.
- chr5:111,070,062–111,739,726, 12 genes, copy number 9 (within-gene range 3–9): TSLP, AC008572.1, WDR36, AC010468.2, RPS3AP21, CAMK4, AC010468.1, AC010275.1, STARD4, STARD4-AS1, HMGN1P13, AC008967.1.
- chr5:133,955,510–181,342,213, 1,032 genes, copy number 8 (broad region; genes not listed).
- chr6:105,919–170,738,536, 2,961 genes, copy number 7 (broad region; genes not listed).
- chr7:37,032–77,198,626, 1,422 genes, copy number 7–18 (within-gene range 6–18) (broad region; genes not listed).
- chr7:77,461,458–95,615,132, 210 genes, copy number 9 (broad region; genes not listed).
- chr7:100,049,774–100,494,802, 40 genes, copy number 8–10: ZSCAN21, ZNF3, COPS6, MCM7, MIR25, MIR93, MIR106B, AP4M1, TAF6, AC073842.2, CNPY4, MBLAC1, AC073842.1, RPL7P60, LAMTOR4, MAP11, MIR4658, GAL3ST4, GPC2, STAG3, CASTOR3, PVRIG, SPDYE3, PMS2P1, Y_RNA, STAG3L5P, STAG3L5P-PVRIG2P-PILRB, PILRB, PVRIG2P, MIR6840, PILRA, AC005071.1, ZCWPW1, MEPCE, AC092849.1, PPP1R35, PPP1R35-AS1, C7orf61, TSC22D4, NYAP1.
- chr7:102,813,230–103,514,007, 22 genes, copy number 7 (within-gene range 6–7): FBXL13, RNU6-1136P, RN7SKP198, LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1.
- chr7:106,774,955–112,206,407, 57 genes, copy number 7–9: LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8, AC073114.1, AC073114.2, IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1, DOCK4, AC003077.1, DOCK4-AS1, RNA5SP237, AC003080.1.
- chr7:148,697,914–159,233,377, 223 genes, copy number 8–10 (within-gene range 5–10) (broad region; genes not listed).
- chr8:38,223,957–145,066,685, 1,626 genes, copy number 7–13 (broad region; genes not listed).
- chr11:77,066,961–79,989,630, 53 genes, copy number 7 (within-gene range 7–9): CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1.
- chr11:86,374,736–87,025,777, 17 genes, copy number 9–19: CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8.
- chr11:94,493,979–95,925,315, 35 genes, copy number 9: ANKRD49, C11orf97, FUT4, PIWIL4, AP000943.2, AP000943.3, AP000943.1, LINC02700, AMOTL1, AP002383.2, ST13P11, CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1, BUD13P1, AP000787.2, AP000787.1, SESN3, AP000787.3, AP001790.1, AP000820.2, AP000820.1, AP001877.1, FAM76B, CEP57, MTMR2, RNA5SP345.
- chr11:96,447,132–97,959,558, 11 genes, copy number 10 (within-gene range 3–10): JRKL-AS1, RNA5SP346, LINC02737, AP003066.1, AP003066.2, MED28P5, AP001836.1, LINC02553, RNA5SP347, LINC02713, AP003730.1.
- chr12:27,243,968–27,972,733, 25 genes, copy number 7: STK38L, ARNTL2, ARNTL2-AS1, SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2.
- chr13:18,538,880–21,235,204, 94 genes, copy number 7 (broad region; genes not listed).
- chr13:48,389,567–53,939,960, 123 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr14:19,954,490–106,879,812, 2,168 genes, copy number 7 (broad region; genes not listed).
- chr16:23,641,466–34,163,110, 483 genes, copy number 7–8 (broad region; genes not listed).
- chr17:14,705,076–46,260,606, 1,348 genes, copy number 9 (broad region; genes not listed).
- chr17:46,503,946–83,240,804, 1,143 genes, copy number 8–9 (broad region; genes not listed).
- chr19:27,638,483–38,426,305, 361 genes, copy number 7 (broad region; genes not listed).
- chr20:19,000,709–20,056,046, 10 genes, copy number 8 (within-gene range 3–8): AL135936.1, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1.
- chr20:21,499,261–32,335,011, 193 genes, copy number 8–13 (broad region; genes not listed).
- chr20:33,657,087–33,854,366, 12 genes, copy number 8: NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B.
- chr20:52,192,159–54,228,052, 29 genes, copy number 10 (within-gene range 5–10): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4.
- chr20:58,218,495–64,327,972, 198 genes, copy number 9–10 (broad region; genes not listed).
- chr21:12,999,676–44,106,552, 600 genes, copy number 7–10 (broad region; genes not listed).
- chr21:44,300,051–46,691,226, 111 genes, copy number 8 (broad region; genes not listed).
- chr22:15,282,557–20,354,387, 228 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr22:22,283,928–25,252,602, 205 genes, copy number 9 (broad region; genes not listed).
- chr22:46,296,870–50,801,309, 104 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 303. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
